Somatic mutation profile of tumor specimen TCGA-DX-AB2F-01A (aliquot TCGA-DX-AB2F-01A-11D-A387-09) from TCGA case TCGA-DX-AB2F, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 76.2 years (27,840 days).
Specimen TCGA-DX-AB2F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39f31e18-5e82-4eea-9dab-02dda445de96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2F-10A (Blood Derived Normal), aliquot TCGA-DX-AB2F-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c9966d9-7a8b-49ef-a758-be0293606514

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Frame Shift Del 2, 3'Flank 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2C2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs371336541; called by muse, varscan2
- BRWD3 | c.1070A>C p.E357A | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100956665; called by muse, mutect2, varscan2
- CABP2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140767804; called by muse, mutect2, varscan2
- CD86 | c.211G>C p.G71R (on ENST00000330540 / NM_175862.5; = p.G65R on NM_006889.4) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100054282; called by muse, mutect2, varscan2
- CHRM2 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs949756685, COSV100282196; called by muse, mutect2, varscan2
- EIF4G3 | c.3773T>C p.F1258S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99946007; called by muse, mutect2, varscan2
- FAM47C | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782659966, COSV100793037; called by muse, mutect2, varscan2
- GARRE1 | c.1090C>G p.L364V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100209858; called by muse, mutect2, varscan2
- GRHL2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV52547060; called by muse, mutect2, varscan2
- IGDCC3 | c.2122G>T p.D708Y | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV100031628; called by muse, mutect2, varscan2
- MMP26 | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100332298; called by muse, mutect2, varscan2
- MYH6 | c.5392C>T p.R1798W | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767251436, COSV100198251; called by muse, mutect2, varscan2
- OR6T1 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.6); PolyPhen benign (0.06); catalogued as COSV100190254, COSV58305807; called by muse, mutect2, varscan2
- PCDHA13 | c.2342G>T p.G781V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99170338; called by muse, mutect2
- PCDHA7 | c.923T>A p.M308K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as COSV100971978; called by muse, mutect2, varscan2
- POT1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs587777476, CM144554, COSV62932457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIX4 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs536442725, COSV99382582; called by muse, mutect2, varscan2
- UGT3A2 | c.1484T>A p.L495H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV99236960; called by muse, mutect2, varscan2
- USP7 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV100784469; called by muse, mutect2, varscan2
- WNK3 | c.1922T>A p.I641N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100672347; called by muse, mutect2, varscan2
- ZNF182 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100527276; called by muse, mutect2, varscan2
- SEC16A | c.4079del p.A1360Dfs*104 | Frame Shift Del (DEL) | VAF 38/131 reads (29%) | called by mutect2, pindel, varscan2
- ZIM2 | c.426del p.E143Kfs*8 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- ABCA3 | c.4455C>T p.G1485= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as COSV100068453; called by muse, mutect2, varscan2
- ACKR4 | c.669A>G p.T223= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs3911405; called by mutect2, varscan2
- OTOA | c.660C>T p.Y220= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs139292090; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA2 | c.1368A>G p.A456= | Silent (SNP) | VAF 82/142 reads (58%) | catalogued as rs375841777; called by muse, mutect2, varscan2
- PIP4K2C | c.612C>A p.R204= | Silent (SNP) | VAF 50/1972 reads (3%) | catalogued as COSV100724046; called by muse, mutect2
- TMPRSS15 | c.792C>T p.S264= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99519630; called by muse, mutect2, varscan2
- AQR | c.471+1057T>A | Intron (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888374 G>T | 3'Flank (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100553253; called by muse, mutect2
- PRORP | c.*1A>G | 3'UTR (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99156782; called by muse, mutect2, varscan2
